Somatic mutation profile of tumor specimen TCGA-G9-6378-01A (aliquot TCGA-G9-6378-01A-11D-1786-08) from TCGA case TCGA-G9-6378, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.4 years (19,879 days).
Specimen TCGA-G9-6378-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b6d2ee2-bcd4-42bf-b23d-816dd327c7bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6378-10A (Blood Derived Normal), aliquot TCGA-G9-6378-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5b7f36a-d3e8-4470-ad0a-407a42ef8aaa

The open-access MAF lists 30 somatic variants for this specimen: 18 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 11, 5'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.910T>C p.W304R | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs766823460, COSV54699737; called by muse, mutect2, varscan2
- AP3B2 | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV55613553; called by muse, mutect2
- CCDC190 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as COSV100905845, COSV63363573; called by muse, mutect2, varscan2
- CYP1A1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV65698059; called by muse, mutect2, varscan2
- DIPK1B | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs766801153, COSV63038277; called by muse, mutect2
- DMXL2 | c.2992+1G>A p.X998_splice | Splice Site (SNP) | VAF 13/89 reads (15%) | catalogued as COSV51854756; called by muse, varscan2
- IFNA13 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs373918648, COSV71924571; called by muse, mutect2, varscan2
- INHBA | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV54221855; called by muse, mutect2, varscan2
- MID1IP1 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61230901; called by muse, mutect2
- NCKAP5L | c.3379G>A p.G1127R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258600, COSV60133295; called by muse, mutect2, varscan2
- NRP2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 30/554 reads (5%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.992); catalogued as rs752149340, COSV55934787; called by muse, mutect2
- OR6K6 | c.403C>A p.L135I (on ENST00000368144; = p.L111I on NM_001005184.1) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV63744808; called by muse, mutect2
- PRRG1 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV66156683, COSV66157691; called by muse, mutect2, varscan2
- PRSS48 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV71614172; called by muse, mutect2, varscan2
- RASAL2 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs962423428, COSV62721864; called by muse, mutect2, varscan2
- SPRR2F | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 54/395 reads (14%) | PolyPhen benign (0.013); catalogued as COSV64207628; called by muse, mutect2, varscan2
- ZFYVE26 | c.7022C>A p.T2341N | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61333036; called by muse, mutect2
- TXNDC11 | c.2047_2052del p.S683_A684del (on ENST00000356957 / NM_001303447.2; = p.S656_A657del on NM_015914.7 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11937C>A p.G3979= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV71293453; called by mutect2, varscan2
- ABCA4 | c.3450C>T p.C1150= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV64677286; called by muse, mutect2, varscan2
- ADGRV1 | c.15411C>T p.F5137= | Silent (SNP) | VAF 47/359 reads (13%) | catalogued as COSV67994089; called by muse, mutect2, varscan2
- GLDN | c.474G>A p.L158= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV59089775; called by muse, mutect2, varscan2
- KLC2 | c.162G>T p.S54= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV57584064; called by muse, mutect2
- KRTAP9-3 | c.138C>T p.C46= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs1220801260, COSV66647073; called by muse, mutect2, varscan2
- MAGEA12 | c.168C>T p.A56= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs1556833340, COSV63295381; called by muse, varscan2
- PPT2 | c.45G>A p.L15= | Silent (SNP) | VAF 37/215 reads (17%) | catalogued as COSV52999516; called by muse, mutect2, varscan2
- PRAG1 | c.318C>G p.A106= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs370861925, COSV58166337; called by muse, mutect2, varscan2
- STK19 | c.357C>T p.I119= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV61714929; called by muse, mutect2, varscan2
- ZFYVE26 | c.7020G>T p.V2340= | Silent (SNP) | VAF 27/241 reads (11%) | catalogued as COSV61333044; called by muse, mutect2
- AP000769.3 | chr11:65505944 del T | 5'Flank (DEL) | VAF 15/126 reads (12%) | called by mutect2, pindel, varscan2
